Surgical pathology report (de-identified scan), TCGA case TCGA-29-2434, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-2434-01A (Primary Tumor).

[page 1 of 3]
TCGA-29-2434

Surg Path

CLINICAL HISTORY:

Ascites. Abdominal/pelvic swelling NOS (illegible).

GROSS EXAMINATION:

A. "Left tube and ovary (AF1)". Unfixed for frozen section and placed in formalin at [REDACTED] is a 270 gm (total), 10.5 x 8 x 6 cm ovary with attached fallopian tube (4 cm long x 0.5 cm in diameter). The ovarian specimen is completely replaced by tumor with no normal ovarian parenchyma identified. The tumor is largely tan-brown in color with multiple areas of fine granularity and some areas of focal necrosis and hemorrhage. Tumor is identified at the outer surface of the ovarian specimen. A representative section of the tumor is frozen as AF1 with the frozen section remnant transferred to block A1. Also, the ovary has a simple, blood-filled cyst which measures 6 x 5 x 5 cm and is noted to have smooth walls. The fallopian tube has a tan-brown, focally congested surface and is adhered and involved by the ovarian lesion.

BLOCK SUMMARY:

A1 frozen section control AF1 (representative tumor)
A2-A4 representative ovarian tumor
A5 representative ovarian simple, blood-filled cyst
A6 representative fallopian tube relative to ovarian tumor

B. "Posterior cul de sac mass and tip of appendix". Unfixed and placed in formalin at [REDACTED] is a 122 gm, 9.4 x 7.9 x 4 cm piece of tan-brown tissue with multiple cystic and solid areas which appears to grossly involve the tip of the appendix (5.1 cm long x 0.9 cm in diameter). The specimen is sectioned to demonstrate a tan-yellow cut surface with multiple solid and cystic spaces. The solid areas are grossly consistent with metastatic tumor and appear to grossly involve the serosal surface of the tip of the appendix. Upon sectioning of the appendix the solid lesions appear to grossly invade the wall of the appendix. The remaining appendix surface is purple-brown and focally hemorrhagic. The margin of the appendix is inked blue. The attached mesoappendix is also grossly involved with the solid lesions.

BLOCK SUMMARY:

B1-B2 representative solid and cystic areas
B3-B4 representative solid and cystic areas relative to the appendix
B5 appendix margin, en face

C. "Right tube and ovary". Unfixed, transferred to formalin at [REDACTED] is a 12 gm, 5 x 3.8 x 3.5 cm piece of tissue consisting of a 2 x 1.1 x 1 cm ovary and a 5 cm x 0.6 cm in diameter fallopian tube. The ovary is sectioned to demonstrate a tan-white, grossly unremarkable cut surface. Representative ovary taken and submitted in block C1. The fallopian tube has a tan-brown grossly unremarkable cut surface. The tube is ligated. The tube is sectioned to demonstrate a grossly unremarkable cut surface. Representative sections of fallopian tube are taken and submitted in block C2. This specimen does not appear to be involved with tumor.

D. "Uterus and cervix". Unfixed, transferred to formalin at 5 pm on [REDACTED] is an 84 gm, 9 x 4 x 3 cm hysterectomy specimen with a 3.5 cm in diameter cervix with a 0.6 cm patent os. The specimen is opened to demonstrate a tan-brown, grossly unremarkable endometrium (less than 0.1 cm thick). The serosal surface of the uterus is remarkable for a focal tan-brown, firm nodularity which measures 3 x 2.5 x 1.7 cm and is grossly consistent with a metastatic tumor.

[page 2 of 3]
The lesion is adherent to the uterine surface but does not appear to grossly invade the myometrium (1.7 cm thick). This nodularity predominantly involves posterolateral wall of the uterus. The remaining serosal surface is tan-brown, smooth, and grossly unremarkable. No myometrial lesions are identified. The cervix and endocervical canal is tan-white, smooth, and grossly unremarkable.

BLOCK SUMMARY:

D1-D2 posterior endomyometrium relative to irregular nodularity
D3 full-thickness anterior endomyometrium
D4 posterior cervix endocervical canal
D5 posterior lower uterine segment
D6 anterior cervix and endocervical canal
D7 anterior lower uterine segment

E. "Stump of appendix". Unfixed, transferred to formalin at [REDACTED] is a 2.6 cm long x 0.6 cm in diameter short segment of appendix with attached mesoappendiceal fat. The appendix surface is tan-purple and focally congested. The appendix is sectioned to demonstrate a tan-white grossly unremarkable cut surface. There are no obstructions. The attached mesoappendix consist of yellow lobulated, grossly unremarkable adipose tissue. No lesions or abnormalities are seen on the specimen. A stapled margin is present at one end of the appendiceal specimen and is removed and inked blue. The inked surgical margin is taken en face and entirely submitted in block E1. Additional representative appendix and mesoappendix are submitted in block E2.

F. "Omentum". Unfixed, transferred to formalin at [REDACTED] is a 396 gm, 39.5 x 21 x 6.5 cm omentum specimen consisting predominantly of yellow-red, lobulated fibroadipose tissue with multiple areas of hemorrhage. The specimen is remarkable for a 6.5 x 6 x 5.3 cm tan-white, firm area of nodularity which is grossly involving and infiltrating the omental fat. The nodularity is grossly consistent with metastatic tumor. The nodularity is sectioned to demonstrate a tan-white, focally hemorrhagic cut surface. Representative sections of the nodularity are submitted in blocks F1-F3. No additional omental lesions are identified. An additional representative section of omental fat is submitted in block F4.

G. "Sigmoid colon nodule". Unfixed, transferred to formalin (time not provided) on [REDACTED] is a 2.4 x 1.5 x 1.5 cm tan-white, firm nodule with attached fibroadipose tissue. The specimen is sectioned to demonstrate a tan-white, solid cut surface. The specimen is entirely submitted in blocks G1-G3.

INTRA OPERATIVE CONSULTATION:

A. "Left tube and ovary" (AF1, representative ovarian tumor): carcinoma, at least focally with serous papillary pattern [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: LEFT SALPINGOOPHORECTOMY

PATHOLOGIC STAGE [REDACTED]: pT3c pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

[page 3 of 3]
DIAGNOSIS:

A. "LEFT TUBE AND OVARY" (SALPINGOOPHORECTOMY):

PAPILLARY SEROUS ADENOCARCINOMA OF OVARY:

Histologic grade: GRADE 3 (POORLY DIFFERENTIATED)

Extent of invasion

- Laterality?	UNILATERAL, LEFT (SEE C)
- Ovarian surface implants?	POSITIVE, EXTENSIVE
- Pelvic surface implants?	POSITIVE
- Implants on uterus/tubes?	POSITIVE (SEE D)
- Other pelvic implants?	POSITIVE (SEE B, D & G)

FIGO Stage: IIIc

B. "POSTERIOR CUL DE SAC MASS AND TIP OF APPENDIX" (RESECTION):

METASTATIC PAPILLARY SEROUS CARCINOMA (9 CM).

C. "RIGHT TUBE AND OVARY" (SALPINGOOPHORECTOMY):

BENIGN OVARY AND FALLOPIAN TUBE.
NEGATIVE FOR MALIGNANCY.

D. "UTERUS AND CERVIX" (HYSTERECTOMY):

METASTATIC PAPILLARY SEROUS CARCINOMA (3 CM) INVOLVING UTERINE SEROSA.

ENDOMETRIUM: ATROPHIC
CERVIX: NO PATHOLOGIC DIAGNOSIS
MYOMETRIUM: NO PATHOLOGIC DIAGNOSIS.

E. "STUMP OF APPENDIX" (APPENDECTOMY):

BENIGN APPENDIX AND MESOAPPENDIX.
NEGATIVE FOR MALIGNANCY.

F. "OMENTUM" (RESECTION):

METASTATIC PAPILLARY SEROUS CARCINOMA (6.5 CM).

G. "SIGMOID COLON NODULE" (RESECTION):

METASTATIC PAPILLARY SEROUS CARCINOMA (2.4 CM).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Performed by:

Source: NCI Genomic Data Commons file 032d2c7f-0621-4c29-b4ea-f5b946eb5141 (TCGA-29-2434.0891AC31-D9ED-4CB3-82AE-8499FB4C29EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).